Surgical pathology report (de-identified scan), TCGA case TCGA-63-6202, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-63-6202-01A (Primary Tumor).

[page 1 of 2]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details							Histology and staging					
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology
	TUMOUR	FF					0	17	RESECT	RUL	6.00	07
	BUFFY	FF					11	28	RESECT	RUL	6.00	07

[page 2 of 2]
Grade/ Differentiation	Pathological T	Pathological N	Clinical M	VALCSG Stage	Histology Comments	Slide URL					
III	T2,NOS	N0	M0								
III	T2,NOS	N0	M0								

Source: NCI Genomic Data Commons file eb35c1b4-f3a6-4f33-9701-9002782ef01f (TCGA-63-6202.B8730165-2C60-469B-AE9A-F630FD97016A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).